Somatic mutation profile of tumor specimen 0DQVIJ from CCDI case PBCFPP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Choroid plexus papilloma, NOS; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 2.0 years (746 days).
Specimen 0DQVIJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 153d7bde-ca1d-4c44-8700-98a9f3bc5242.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQVIY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b992a142-c5bd-4bca-ba45-6765d3a822ce

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 54/1716 reads (3%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- GTF2A1 | c.1043A>G p.K348R | Missense Mutation (SNP) | VAF 136/448 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 30/866 reads (3%) | catalogued as rs1167537044; called by muse, mutect2
- USF3 | c.3408A>T p.A1136= | Silent (SNP) | VAF 64/1854 reads (3%) | catalogued as COSV57072566; called by muse, mutect2
- FRAS1 | c.5856+113A>T | Intron (SNP) | VAF 19/512 reads (4%) | called by muse, mutect2
